Surgical pathology report (de-identified scan), TCGA case TCGA-HJ-7597, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Fox Chase, specimen TCGA-HJ-7597-01A (Primary Tumor).

[page 1 of 4]
SPECIMENS:

- A. SMALL BOWEL NODULE
- B. RT OVARY AND TUBE
- C. LEFT OVARY AND TUBE
- D. REPLACED LEFT HEPATIC ARTERY LYMPH NODE
- E. RIGHT CARDIA LYMPH NODE
- F. LEFT CARDIA LYMPH NODE
- G. POSTERIOR LEFT GASTRIC LYMPH NODE
- H. NODULE ON STOMACH GREATER CURVATURE
- I. LESSER CURVATURE AND PROXIMAL STOMACH
- J. RIGHT HEPATIC NODE
- K. GALLBLADDER

DIAGNOSIS:

- A. SOFT TISSUE, SMALL BOWEL NODULE, EXCISION:
- PERITONEAL INCLUSION CYST.
- NO MALIGNANCY IDENTIFIED.
- B. OVARY AND FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY:
- OVARY:
- BENIGN BRENNER'S TUMOR.
- FALLOPIAN TUBE:
- NO HISTOPATHOLOGICAL ABNORMALITIES.
- C. OVARY AND FALLOPIAN TUBE, LEFT, SALPINGO-OOPHORECTOMY:
- OVARY:
- BENIGN BRENNER'S TUMOR.
- FALLOPIAN TUBE:
- PARATUBAL CYST.
- D. LYMPH NODE, LEFT HEPATIC ARTERY, EXCISION:
- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE (0/1).
- E. LYMPH NODE, RIGHT GASTRIC CARDIA, EXCISION:
- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE (0/1).
- F. LYMPH NODE, LEFT GASTRIC CARDIA, EXCISION:
- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE (0/1).
- G. LYMPH NODE, POSTERIOR LEFT GASTRIC, EXCISION:
- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE (0/1).
- H. SOFT TISSUE, GREATER CURVATURE NODULE, EXCISION:
- PERITONEAL INCLUSION CYST.
- NO MALIGNANCY IDENTIFIED.
- I. STOMACH, PARTIAL GASTRECTOMY:
- INVASIVE ADENOCARCINOMA WITH A SIGNET RING CELL COMPONENT, POORLY DIFFERENTIATED, SEE TEMPLATE.
- 6.5 CM IN GREATEST DIMENSION.
- 5.5 X 2.0 CM IN ADDITIONAL DIMENSIONS.
- ULCERATED.
- INVADING INTO THE SUBSEROA.
- THE INVASIVE CARCINOMA IS <0.1 CM FROM THE SEROSAL SURFACE.
- THE PROXIMAL, DISTAL AND RADIAL MARGINS ARE NEGATIVE FOR TUMOR.
- THE INVASIVE TUMOR IS 3.0 CM FROM THE PROXIMAL MARGIN (CLOSEST MARGIN).
- ANGIOLYMPHATIC INVASION IS PRESENT.
- PERINEURAL INVASION IS PRESENT.
- ADENOCARCINOMA IN-SITU IS PRESENT.

[page 2 of 4]
- THE NON-NEOPLASTIC STOMACH SHOWS INTESTINAL METAPLASIA.
- NO MALIGNANCY IDENTIFIED IN TWENTY-NINE LYMPH NODES (0/29).

J. LYMPH NODES, RIGHT HEPATIC, EXCISION:

- NO MALIGNANCY IDENTIFIED IN FOUR LYMPH NODES (0/4).

K. GALLBLADDER, CHOLECYSTECTOMY:

- MILD CHRONIC CHOLECYSTITIS.
- CHOLELITHIASIS.

STOMACH CANCER TEMPLATE

Specimen type:	Distal subtotal gastrectomy
Tumor configuration:	Ulcerating
Tumor size:	6.5 x 5.5 x 2.0 cm
Histologic type:	Adenocarcinoma
Histologic grade:	Poor
Extent of invasion:	Subserosa
Margins:	Uninvolved
Distance from closest margin:	3 cm (proximal margin)
Venous/lymphatic invasion:	Present
Perineural invasion:	Present
Additional pathologic findings:	Intestinal metaplasia
Extent of resection:	R0: Complete with negative margins
Lymph nodes:	Negative (0/37)
Implants:	Absent
Pathologic Stage:	pT2b N0 MX

SPECIMEN(S):

A. SMALL BOWEL NODULE B. RT OVARY AND TUBE C. LEFT OVARY AND TUBE D. REPLACED LEFT HEPATIC ARTERY LYMPH NODE E. RIGHT CARDIA LYMPH NODE F. LEFT CARDIA LYMPH NODE G. POSTERIOR LEFT GASTRIC LYMPH NODE H. NODULE ON STOMACH GREATER CURVATURE I. LESSER CURVATURE AND PROXIMAL STOMACH J. RIGHT HEPATIC NODE K. GALLBLADDER

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSA: Small bowel nodule, biopsy: Benign epithelial inclusion cyst. By [REDACTED] called to [REDACTED]
FSB, FSC: Bilateral ovaries: Benign adenofibromatous nodules. No metastatic malignancy identified. Benign Brenner's tumor also possible. By [REDACTED] called to [REDACTED]
FSH: Stomach, gastric curvature nodule, biopsy: Negative for malignancy. By [REDACTED] called to [REDACTED]
FSI: Stomach, partial gastrectomy: Proximal and distal margins negative for malignancy. By [REDACTED] called to [REDACTED] at [REDACTED]

GROSS DESCRIPTION:

SMALL BOWEL NODULE

Received fresh for frozen section, labeled with the patient's name, unit number and "small bowel nodule" is a 0.3 cm in diameter fragment of yellow soft tissue. The specimen is entirely submitted for frozen section and now resubmitted in cassette labeled FSA1.

B. RIGHT OVARY AND TUBE

Received fresh for frozen section, labeled with the patient's name, unit number and "right ovary and tube" is a 16 gm right salpingo-oophorectomy specimen. The ovary is 3.5 x 3.0 x 2.7 cm and has a yellow smooth surface. The cut surface of the ovary is yellow, firm, smooth, and partially calcified. The right fallopian tube is 4.0 cm long, and 0.4 cm in diameter. The fallopian tube contains multiple paratubal cysts along its length. It is loosely attached to the right ovary by soft tissue and is grossly unremarkable. A portion of the ovary is submitted for frozen section and resubmitted in a cassette labeled FSB1. Representative sections of the ovary and fallopian tube are submitted in cassettes B2 and B3. Block summary:

[page 3 of 4]
FSB1: frozen section control of ovary
B2-B3: representative sections of ovary and fallopian tube

LEFT OVARY AND TUBE

Received fresh for frozen section, labeled with the patient's name, unit number and "left ovary and tube" is a 5 gm left salpingo-oophorectomy specimen. The ovary is 2.5 x 1.2 x 1.0 cm with a yellow smooth surface. A 2.2 cm in diameter cyst is adjacent to the ovary. The cut surface of the ovary reveals yellow ovarian tissue. The left fallopian tube is 3.5 cm long, and 0.4 cm in diameter. It is attached to the ovary by soft tissue and is grossly unremarkable. A portion of the ovary is submitted for frozen section and resubmitted in a cassette labeled FSC1. Representative section of the ovary and fallopian tube are submitted in a cassette labeled C2. Block summary:

FSC1: frozen section control of ovary
C2: representative sections of ovary and fallopian tube

REPLACED LEFT HEPATIC ARTERY LYMPH NODE

Received in a container labeled with the patient's name and "replaced left hepatic artery LN" is a 0.5 cm tan lymph node. The specimen is completely submitted in a cassette labeled D1.

RIGHT CARDIA LYMPH NODE

Received in a container labeled with the patient's name and "right cardia LN" is a 2.5 x 2.0 x 0.3 cm portion of adipose containing a lymph node. The specimen is completely submitted in a cassette labeled E1.

LEFT CARDIA LYMPH NODE

Received in a container labeled with the patient's name and "left cardia LN" is a 2.2 x 1.6 x 0.7 cm portion of adipose containing a lymph node. The specimen is bisected and completely submitted in a cassette labeled F1.

POSTERIOR LEFT GASTRIC LYMPH NODE

Received in a container labeled with the patient's name and "posterior left gastric LN" is a 2.4 x 1.5 x 1.0 cm portion of adipose containing a lymph node. The specimen is bisected and completely submitted in a cassette labeled G1.

NODULE ON STOMACH GREATER CURVATURE

Received fresh for frozen section, labeled with the patient's name, unit number and "nodule on stomach greater curvature" is a 0.9 x 0.5 x 0.3 cm portion of soft tissue containing cysts that have cloudy yellow fluid. The specimen is entirely submitted for frozen section and resubmitted in a cassette labeled FSH.

LESSER CURVATURE AND PROXIMAL STOMACH

Received fresh for frozen section, labeled with the patient's name, unit number and "lesser curvature and proximal stomach" is a 18 x 10 x 5 cm partial gastrectomy specimen. The specimen is oriented with a suture designating the proximal margin. The lesser curvature is 12 cm long and has an attached 7 x 4 x 3 cm portion of adipose tissue. The greater curvature is 19.5 cm long and has an attached 33.5 x 15 x 3 cm portion of adipose tissue. A 6.5 x 5.5 x 2.0 cm ulcerated tumor with raised edges is present in the lesser curvature. The tumor is 3.0 cm from the proximal margin and 7.5 cm from the distal margin. The tumor extends through the muscularis propria and approaches the serosal surface. The remaining gastric mucosa contains normal rugal folds and is grossly unremarkable. Dissection reveals 24 possible lymph nodes. The portion of the distal and proximal margins were shaved and submitted for frozen section and are resubmitted in cassettes labeled FSI12 and FSI13. Representative sections are submitted in 28 cassettes labeled FSI1-I28. Block summary:

FSI12: proximal shaved margin
FSI13: distal shaved margin
I1-I2: proximal margin
I3: distal margin
I4-I6: tumor from proximal to distal
I7-I9: tumor from proximal distal
I10, I11: random stomach
I12: 1 lymph node
I14-I18: 1 lymph node in each cassette, lesser curvature
I19: 5 lymph nodes, lesser curvature
I20-I26: 2 lymph nodes in each cassette, greater curvature
I27-I28: tumor

[page 4 of 4]
[REDACTED]

RIGHT HEPATIC NODE

Received in a container labeled with the patient's name and "right hepatic lymph node" is a 3.0 x 2.4 x 1.5 cm portion of adipose containing lymph nodes. Four possible lymph nodes are identified.

J1: 1 node, bisected

J2: 1 node, bisected

J3: 2 possible nodes

GALLBLADDER

Received in a container labeled with the patient's name and "gallbladder" is a 9.0 x 3.5 x 3.2 cm gallbladder. The serosal surface is smooth and slightly green. The gallbladder contains thick green bile and a single 2.0 cm in diameter stone. The mucosa shows patchy attenuation and is bile stained. The cystic duct ranges up to 0.3 cm in diameter. The thickness is focally up to 0.4 cm, but it is largely 0.2 cm in thickness. Representative sections of body, fundus and cystic duct are submitted in cassette K1.

Gross Dictation:, Pathology Fellow, [REDACTED]

Microscopic/Diagnostic Dictation:., Pathologist, [REDACTED]

Final Review:., Pathologist, [REDACTED]

Final:., Pathologist [REDACTED]

Source: NCI Genomic Data Commons file fe040943-0d09-4b31-9719-f2771759855e (TCGA-HJ-7597.CAF9A0A4-2045-4A72-9A3E-39A09A85A0D9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).